Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAPU, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAPU-01A (Primary Tumor).

[page 1 of 3]
TSS Patient ID:

Surgical Date:

Gross Description: Whipple, FS: Received is a Whipple specimen consisting of duodenum and pancreas. The duodenum measures 19 cm in length x 2.5-3.5 cm in diameter. Both ends are stapled closed. The serosa is smooth, tan-pink, and the stapled margins are inked black. The duodenum is opened and reveals a stent in the ampulla and a 1.5 x 1-cm area of flattened mucosa with underlying palpable, indurated mass 3 cm proximal to the ampulla. The proximal duodenal margin is removed entirely en face and used for frozen section diagnosis and is resubmitted in toto. The pancreas measures 5.8 x 4 x 4 cm. The neck margin is inked blue, and the radial margin is inked black. On sectioning, a 4 x 3.8 x 3-cm, ill-defined, indurated, white-yellow mass with clear tan, mucinous filled cystic spaces is identified in the head of the pancreas, 0.6 cm to the neck

margin, approximately 0.2 cm to the ampulla, and focally abuts the black-inked radial margin, and grossly extends to the proximal duodenal margin.

*ICD. O-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreas head
C25.0
#0 5/16/14*

The ill-defined mass surrounds the main pancreatic and common bile ducts; however, both ducts are probe patent through the ampulla. The common bile duct contains a blue stent. The ducts appear to enter the duodenum via adjacent but separate ductal ampullae. Common bile duct at the margin is dilated at 1 cm in diameter. The main pancreatic duct at the neck margin is dilated up to 0.6 cm in diameter.

Sectioning through the mass into the duodenum proximal to the ampulla reveals the mass to extend grossly into the muscularis of the duodenum and a clear, mucinous, fluid-filled space, 1.4 cm in greatest dimension, subjacent to the flattened duodenal mucosal area.

Sectioning and palpation of the peripancreatic fat reveals 14 possible lymph nodes ranging in size from 0.3 cm in greatest dimension up to 1.2 cm in greatest dimension. Additionally noted is a 4.2 x 3.2 x 0.6-cm, lymph node versus splenule. All possible lymphoid tissue is submitted.

Representative sections of the largest lymph node versus splenule are

[page 2 of 3]
submitted. Representative sections are submitted.

Microscopic Description:

Diagnosis Details: Pancreas and duodenum, Whipple:

- Ductal adenocarcinoma of the pancreas, moderately differentiated
- Size: 4 cm in greatest dimension
- Tumor invades through the muscularis propria of the duodenum and also extends into peripancreatic fat
- Tumor is present at the pancreatic neck margin of the specimen (see specimen E for final margin)
- Tumor extends to the proximal duodenal margin (see specimen H for final margin)
- Tumor is within 0.1 cm of the portal vein margin and radial margins
- Perineural invasion identified
- Negative for angiolymphatic invasion
- AJCC stage: pT3 pN0 MX
- Twelve lymph nodes, negative for malignancy (0/12)

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

Tumor size: 4 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Moderately differentiated

Tumor extent: Other - Small intestines

Lymph nodes: 0/12 positive for metastasis (Regional 0/12)

Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Involved

[page 3 of 3]
Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 24ba8c95-dce0-4d44-8868-4128728f6f77 (TCGA-FB-AAPU.BFB2AE34-A643-41B4-94FB-E5C9AD1F3F58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).